Somatic mutation profile of tumor specimen HCM-STAN-0627-C34-01A (aliquot HCM-STAN-0627-C34-01A-11D-A85C-36) from HCMI case HCM-STAN-0627-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,727 days).
Specimen HCM-STAN-0627-C34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44c1112b-d49c-48c4-b8c1-577df08e06c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0627-C34-10A (Blood Derived Normal), aliquot HCM-STAN-0627-C34-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76905001-480d-4343-8dac-bad5b89c0e78

The open-access MAF lists 326 somatic variants for this specimen: 243 protein-altering or splice-affecting, 64 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 64, Nonsense Mutation 15, Frame Shift Del 9, Intron 8, 3'UTR 4, 5'Flank 3, Frame Shift Ins 3, 5'UTR 3, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 263/655 reads (40%) | hotspot (GDC flag); catalogued as rs141798398, CM072935, COSV58687783, COSV58689693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 115/479 reads (24%) | catalogued as rs1555398283, CM972806; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 174/599 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY7 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 157/674 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs562841900; called by muse, mutect2, varscan2
- ADRA1A | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 146/431 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370056; called by muse, mutect2, varscan2
- ALDH1A2 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 100/414 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1484902253; called by muse, varscan2
- ALDH1A3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 196/750 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1432494592; called by muse, varscan2
- ATP2A1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 74/720 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs770770067, COSV63920624; called by muse, mutect2, varscan2
- ATP5F1C | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV59623121; called by muse, mutect2, varscan2
- BMP6 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 131/465 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51666517; called by muse, mutect2, varscan2
- C8A | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 102/476 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as COSV63483235; called by muse, mutect2, varscan2
- CAGE1 | c.2179G>T p.A727S (on ENST00000512086; = p.A591S on NM_205864.3) | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV57077070; called by mutect2, varscan2
- CD109 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 89/336 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV54648959; called by muse, mutect2, varscan2
- CFAP99 | c.259G>C p.E87Q (on ENST00000506607; = p.E572Q on NM_001193282.3) | Missense Mutation (SNP) | VAF 261/697 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV72247048; called by muse, mutect2
- CLU | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs543267224, COSV57066235; called by muse, mutect2, varscan2
- CNKSR2 | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 224/420 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54250742; called by muse, varscan2
- CNTNAP5 | c.517G>C p.G173R | Missense Mutation (SNP) | VAF 166/415 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70497184, COSV70507647; called by muse, mutect2, varscan2
- COL22A1 | c.4855C>T p.R1619W | Missense Mutation (SNP) | VAF 114/466 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755307992, COSV57325647; called by muse, varscan2
- COL4A2 | c.4954G>A p.A1652T | Missense Mutation (SNP) | VAF 197/955 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); catalogued as rs763103910, COSV100847246, COSV64633658; called by muse, mutect2, varscan2
- CSMD3 | c.2162G>A p.C721Y (on ENST00000297405 / NM_001363185.1; = p.C617Y on NM_052900.3) | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52334742, COSV99836666; called by muse, mutect2, varscan2
- CUL3 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 177/483 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV52363848, COSV52372958; called by muse, mutect2, varscan2
- CXCR2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59282035; called by muse, mutect2, varscan2
- DNAH5 | c.2535G>T p.Q845H | Missense Mutation (SNP) | VAF 207/545 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs757277607; called by muse, mutect2, varscan2
- DZIP3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 64/392 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs368033775; called by muse, mutect2, varscan2
- EPHA6 | c.2387G>T p.R796I (on ENST00000389672 / NM_001080448.3; = p.R188I on NM_173655.4) | Missense Mutation (SNP) | VAF 220/431 reads (51%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.809); catalogued as COSV101064895, COSV67559861; called by muse, mutect2, varscan2
- ERMARD | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 124/461 reads (27%) | catalogued as COSV100824891, COSV64652273; called by muse, mutect2, varscan2
- EXOC6 | c.2240A>G p.Y747C | Missense Mutation (SNP) | VAF 119/429 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363932301; called by muse, mutect2, varscan2
- FAM83H | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 308/1033 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1430530122, COSV66353552; called by muse, varscan2
- FLRT2 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 168/649 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as rs538772019, COSV58136450; called by muse, mutect2, varscan2
- GPRC6A | c.2744C>A p.S915Y | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59955761; called by muse, varscan2
- GRIN2A | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 134/489 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs1240144483; called by muse, mutect2, varscan2
- GRIN2B | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 916/1185 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV74206378; called by muse, mutect2, varscan2
- GRIN2B | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 722/974 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs1280718157; called by muse, varscan2
- IGSF21 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 144/512 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs201284891, COSV52124955, COSV99246413; called by muse, varscan2
- KL | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 234/462 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as rs199676672, COSV66309227; called by muse, varscan2
- KRIT1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 132/1870 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1480771068, COSV60670506; called by muse, mutect2
- L3MBTL1 | c.1711-1G>T p.X571_splice (on ENST00000418998 / NM_001377303.1; = p.X481_splice on NM_015478.7) | Splice Site (SNP) | VAF 133/406 reads (33%) | catalogued as rs1159705449; called by muse, mutect2, varscan2
- LAMA1 | c.5796G>T p.L1932= | Splice Region (SNP) | VAF 70/326 reads (21%) | catalogued as rs1203740341; called by muse, mutect2, varscan2
- LAP3 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 146/423 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV56898101; called by muse, mutect2, varscan2
- LATS1 | c.2589G>C p.Q863H | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1283487068; called by muse, varscan2
- LRRCC1 | c.2320G>C p.A774P | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99066558; called by muse, mutect2, varscan2
- LRRTM4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297645; called by muse, varscan2
- MAGEC1 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV99595479; called by muse, mutect2, varscan2
- MBLAC1 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 906/1238 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV53542929; called by muse, varscan2
- METTL26 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 132/488 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100037220; called by muse, varscan2
- MRPL55 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 164/861 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54342003; called by muse, mutect2, varscan2
- MS4A14 | c.650T>C p.L217S | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.224); catalogued as rs370208539; called by muse, mutect2, varscan2
- MUC15 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 172/337 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55554945; called by muse, varscan2
- MYO9A | c.1786A>G p.I596V | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1328861103; called by muse, mutect2, varscan2
- NCAM2 | c.196A>T p.R66W | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53108385; called by muse, mutect2, varscan2
- NCAN | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 136/614 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748873332; called by muse, varscan2
- NDRG4 | c.1015G>A p.E339K (on ENST00000570248 / NM_001378344.1; = p.E358K on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/697 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs918762728; called by muse, mutect2, varscan2
- NEXN | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1332725424; called by muse, mutect2, varscan2
- NLRP13 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 172/476 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.186); catalogued as rs184435930, COSV99048659; called by muse, varscan2
- NLRP5 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 289/700 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993605597, COSV101173910; called by muse, mutect2, varscan2
- NTRK3 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 117/485 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374759890; called by muse, varscan2
- NUDT19 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 208/932 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs891378669; called by muse, varscan2
- OPRK1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 142/580 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55572641, COSV55572689; called by muse, varscan2
- OR10H1 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 252/1095 reads (23%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as rs1357839250; called by muse, mutect2, varscan2
- OR10J1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 146/687 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs141763562; called by muse, mutect2, varscan2
- OR4K17 | c.381T>A p.C127* | Nonsense Mutation (SNP) | VAF 93/337 reads (28%) | catalogued as COSV59649148; called by muse, mutect2, varscan2
- OR5B21 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as rs992774321; called by muse, mutect2, varscan2
- OR5I1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 98/455 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV56885869; called by muse, mutect2, varscan2
- OR6B3 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 135/316 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs1330355017; called by muse, varscan2
- OR6N1 | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 268/455 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100625017; called by muse, mutect2
- OR6N1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 156/674 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs760792253, COSV58647460; called by muse, varscan2
- OR8K3 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV57130713, COSV57130774; called by muse, varscan2
- OTOA | c.3394G>A p.A1132T (on ENST00000286149; = p.A1118T on NM_144672.4) | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1461905781; called by muse, mutect2, varscan2
- OTOF | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 255/900 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs397517934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 177/663 reads (27%) | catalogued as COSV52032846; called by muse, mutect2, varscan2
- PDE6A | c.2049G>C p.K683N | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV99678506; called by muse, mutect2, varscan2
- PIK3R5 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 151/513 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs757328494; called by muse, mutect2, varscan2
- PIK3R6 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 127/408 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs1372719081; called by muse, mutect2, varscan2
- PIWIL1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 162/638 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs750461577, COSV55343720; called by muse, mutect2, varscan2
- PIWIL1 | c.24A>C p.R8S | Missense Mutation (SNP) | VAF 161/639 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs971930535; called by muse, mutect2, varscan2
- PNLIPRP1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 132/512 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998634455; called by muse, varscan2
- PRUNE2 | c.6893C>T p.A2298V | Missense Mutation (SNP) | VAF 102/439 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV65038010; called by muse, varscan2
- RAPH1 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs931579112; called by muse, mutect2, varscan2
- RASGRF1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 141/581 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV69183490; called by muse, mutect2, varscan2
- REG3A | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 156/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59409090; called by muse, varscan2
- REG3A | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs781494401; called by muse, varscan2
- RHBDF1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 126/433 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV99032514; called by muse, varscan2
- RHBDL1 | c.802C>T p.Q268* (on ENST00000219551 / NM_001318733.2; = p.Q203* on NM_001278720.2) | Nonsense Mutation (SNP) | VAF 168/688 reads (24%) | catalogued as rs1223788193; called by muse, varscan2
- RUBCNL | c.1651C>A p.Q551K | Missense Mutation (SNP) | VAF 180/347 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV59792576; called by muse, mutect2, varscan2
- RYR2 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 326/549 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1232224119, COSV63720247; called by muse, mutect2, varscan2
- SAGE1 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 141/223 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV61015085; called by muse, mutect2, varscan2
- SAMD5 | c.203A>T p.N68I | Missense Mutation (SNP) | VAF 228/868 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs759678529; called by muse, mutect2, varscan2
- SCAMP1 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100210360; called by muse, mutect2, varscan2
- SENP3 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 63/460 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.587); catalogued as COSV53435810; called by muse, mutect2, varscan2
- SLC5A5 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 125/624 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs149406361; called by muse, varscan2
- SRC | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 25/981 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV62441275; called by muse, mutect2
- SYNE1 | c.23953G>T p.A7985S (on ENST00000367255 / NM_182961.4; = p.A7914S on NM_033071.3) | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563082229; called by muse, mutect2, varscan2
- TAS2R41 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 129/344 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as COSV99065175; called by muse, mutect2, varscan2
- TGIF2LX | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV52214313; called by muse, mutect2, varscan2
- THSD1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 198/366 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV51630014; called by muse, mutect2, varscan2
- TOP3A | c.2288C>G p.S763C | Missense Mutation (SNP) | VAF 163/577 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as COSV58181892; called by muse, varscan2
- UTRN | c.3569A>G p.K1190R | Missense Mutation (SNP) | VAF 108/429 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV100839427; called by muse, mutect2, varscan2
- ZNF280A | c.900C>A p.C300* | Nonsense Mutation (SNP) | VAF 696/1198 reads (58%) | catalogued as COSV57481684; called by muse, varscan2
- ZNF423 | c.1609G>T p.E537* (on ENST00000563137 / NM_001379286.1; = p.E529* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 282/672 reads (42%) | catalogued as rs1555515547; called by muse, varscan2
- AASDH | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 14/512 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ABCA12 | c.4651G>C p.E1551Q (on ENST00000272895 / NM_173076.3; = p.E1233Q on NM_015657.3) | Missense Mutation (SNP) | VAF 120/362 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ADCY1 | c.1276G>C p.A426P | Missense Mutation (SNP) | VAF 114/424 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY3 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADGRB3 | c.1993C>G p.Q665E | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ADGRV1 | c.8908G>C p.E2970Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2
- ALDH1A3 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 194/746 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.125); called by muse, varscan2
- ALPG | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 132/426 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMPD1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 121/512 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ANKRD36 | c.4411G>A p.A1471T | Missense Mutation (SNP) | VAF 130/552 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); called by muse, varscan2
- AQP9 | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 119/434 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID1A | c.2776_2777dup p.G927Lfs*15 | Frame Shift Ins (INS) | VAF 122/569 reads (21%) | called by mutect2, pindel, varscan2
- ASIC2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 123/450 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATG12 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP6V1E1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ATP7A | c.609A>T p.K203N | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- B3GALT1 | c.799T>C p.Y267H | Missense Mutation (SNP) | VAF 144/742 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BAHCC1 | c.3652A>G p.R1218G | Missense Mutation (SNP) | VAF 202/808 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, varscan2
- C10orf67 | c.1393C>G p.R465G | Missense Mutation (SNP) | VAF 119/473 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C10orf71 | c.3465del p.R1156Dfs*8 | Frame Shift Del (DEL) | VAF 144/704 reads (20%) | called by pindel, varscan2
- C4orf33 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CAPN3 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 120/421 reads (29%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CCDC168 | c.15392A>T p.K5131M | Missense Mutation (SNP) | VAF 478/739 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CCDC7 | c.1454G>T p.S485I (on ENST00000639629 / NM_001321115.2; = p.R485I on NM_145023.6) | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CCR3 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCT8 | c.587A>T p.H196L | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHSY3 | c.1632A>T p.L544F | Missense Mutation (SNP) | VAF 108/436 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, varscan2
- CLOCK | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 98/282 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- COG5 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 217/440 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- COL3A1 | c.1582G>T p.G528C | Missense Mutation (SNP) | VAF 92/490 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 92/497 reads (19%) | called by muse, mutect2, varscan2
- CPNE8 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CSMD3 | c.8027C>A p.S2676* (on ENST00000297405 / NM_001363185.1; = p.S2572* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 90/424 reads (21%) | called by muse, mutect2, varscan2
- CSMD3 | c.5624C>G p.S1875C (on ENST00000297405 / NM_001363185.1; = p.S1771C on NM_052900.3) | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CTSZ | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 194/750 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.5258G>A p.G1753D | Missense Mutation (SNP) | VAF 91/425 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CXorf21 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- DDX60 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX32 | c.1775T>A p.L592* | Nonsense Mutation (SNP) | VAF 130/562 reads (23%) | called by mutect2, varscan2
- DNAH14 | c.1561G>T p.E521* (on ENST00000445597; = p.E502* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- EBF1 | c.912G>T p.L304F | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ECD | c.21dup p.A8Cfs*17 | Frame Shift Ins (INS) | VAF 82/388 reads (21%) | called by mutect2, pindel, varscan2
- ECM2 | c.1311A>T p.L437F | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EGLN1 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 156/783 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ENPEP | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 162/485 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- EPS15 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 86/371 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ERI3 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 172/622 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, varscan2
- FAM236C | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, varscan2
- FBXO30 | c.1584A>T p.R528S | Missense Mutation (SNP) | VAF 104/430 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FGF13 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); called by muse, varscan2
- FHOD3 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 194/546 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FLG | c.9557C>G p.S3186C | Missense Mutation (SNP) | VAF 324/789 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, varscan2
- FN1 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- FRMD6 | c.1145C>G p.S382C (on ENST00000344768 / NM_001267046.2; = p.S374C on NM_152330.4) | Missense Mutation (SNP) | VAF 24/734 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FZD9 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 194/729 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- GRHL3 | c.818C>T p.A273V (on ENST00000350501 / NM_198174.3; = p.A278V on NM_021180.3) | Missense Mutation (SNP) | VAF 136/534 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GRM6 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 110/525 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- GRPR | c.613del p.L205Ffs*33 | Frame Shift Del (DEL) | VAF 163/384 reads (42%) | called by mutect2, pindel, varscan2
- HDGFL2 | c.805T>C p.S269P | Missense Mutation (SNP) | VAF 370/817 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); called by muse, varscan2
- HS3ST5 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 118/510 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- HSD3B2 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 146/575 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, varscan2
- HTR3A | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); called by muse, varscan2
- INSC | c.953dup p.E319Gfs*25 | Frame Shift Ins (INS) | VAF 109/447 reads (24%) | called by mutect2, pindel, varscan2
- ITGAX | c.2986C>A p.L996I | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, varscan2
- JAK2 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13B | c.2533G>T p.G845W | Missense Mutation (SNP) | VAF 117/348 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, varscan2
- KIF4B | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 208/769 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KRTAP10-6 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 278/944 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.281); called by muse, varscan2
- LDLRAD4 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 237/791 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LILRB1 | c.1256C>A p.P419H (on ENST00000427581; = p.P383H on NM_006669.6) | Missense Mutation (SNP) | VAF 205/995 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, varscan2
- LMBRD1 | c.667A>G p.T223A (on ENST00000649011; = p.T201A on NM_018368.4) | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- METTL21A | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 127/349 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MGAT4B | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 19/661 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MT1HL1 | c.107G>C p.C36S | Missense Mutation (SNP) | VAF 207/983 reads (21%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- MYLK | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 566/1090 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYO9A | c.3965C>G p.P1322R | Missense Mutation (SNP) | VAF 21/495 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NBEA | c.7476C>A p.C2492* | Nonsense Mutation (SNP) | VAF 160/294 reads (54%) | called by muse, mutect2, varscan2
- NCOA2 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 125/457 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEK6 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 148/640 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIPAL4 | c.499T>C p.W167R | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1AP | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 244/410 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSFL1C | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 127/494 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.3); called by muse, varscan2
- NUP153 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 157/514 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.17026G>A p.E5676K | Missense Mutation (SNP) | VAF 128/658 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OGFRL1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 185/694 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR2L8 | c.403A>T p.M135L | Missense Mutation (SNP) | VAF 204/810 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, varscan2
- OR2M2 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 384/615 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR4A47 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 105/481 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4A5 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); called by muse, varscan2
- OR4D2 | c.360del p.F120Lfs*17 | Frame Shift Del (DEL) | VAF 120/526 reads (23%) | called by pindel, varscan2
- OR4N2 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 66/590 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by mutect2, varscan2
- OR51D1 | c.128del p.P43Hfs*14 | Frame Shift Del (DEL) | VAF 170/668 reads (25%) | called by pindel, varscan2
- OXLD1 | c.37_46del p.V13Rfs*47 | Frame Shift Del (DEL) | VAF 256/1098 reads (23%) | called by mutect2, pindel, varscan2
- PEX5L | c.1583T>C p.V528A | Missense Mutation (SNP) | VAF 130/903 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3C2B | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 316/504 reads (63%) | SIFT tolerated (0.43); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PLPPR4 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 144/520 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); called by muse, varscan2
- POLRMT | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 182/959 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- PPFIA1 | c.3503C>G p.S1168C | Missense Mutation (SNP) | VAF 334/3778 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- PRLHR | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 93/384 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PTPRB | c.4745G>C p.R1582P | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- REXO1 | c.2462A>C p.Y821S | Missense Mutation (SNP) | VAF 98/509 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- RNF150 | c.616del p.R206Afs*14 | Frame Shift Del (DEL) | VAF 129/385 reads (34%) | called by mutect2, pindel, varscan2
- S100A12 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 136/665 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SATB2 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SGK1 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGPP1 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 192/626 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- SIGLEC5 | c.1630T>A p.Y544N | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIRT6 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 208/958 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC6A14 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 104/184 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SOX11 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 154/605 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SPATA33 | c.58A>T p.T20S | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, varscan2
- SSX5 | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 156/273 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYMPK | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 105/533 reads (20%) | called by muse, mutect2, varscan2
- TECPR2 | c.2354G>T p.R785L | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TINAG | c.350del p.P117Qfs*16 | Frame Shift Del (DEL) | VAF 69/329 reads (21%) | called by mutect2, pindel, varscan2
- TM4SF18 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 16/521 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- TRAFD1 | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 92/379 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TRAV12-3 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TRIM77 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 111/335 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRIOBP | c.5018del p.P1673Qfs*48 | Frame Shift Del (DEL) | VAF 193/735 reads (26%) | called by mutect2, pindel, varscan2
- TRPM1 | c.2686C>G p.Q896E | Missense Mutation (SNP) | VAF 135/575 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TTN | c.37167A>T p.Q12389H (on ENST00000591111; = p.Q4965H on NM_003319.4) | Missense Mutation (SNP) | VAF 95/458 reads (21%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.25052G>A p.G8351D (on ENST00000591111; = p.G7424D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/729 reads (18%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTYH1 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 301/678 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- UBR4 | c.14467C>A p.L4823I | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); called by muse, varscan2
- UBXN11 | c.812C>T p.S271L (on ENST00000374221 / NM_183008.2; = p.S238L on NM_145345.2) | Missense Mutation (SNP) | VAF 135/509 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USH2A | c.9011A>G p.H3004R | Missense Mutation (SNP) | VAF 92/529 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- USP40 | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 157/365 reads (43%) | called by muse, mutect2, varscan2
- USP9X | c.1924G>C p.V642L | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, varscan2
- VPS13A | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13D | c.11031G>T p.E3677D | Missense Mutation (SNP) | VAF 157/497 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- VSIG10L | c.1941C>A p.D647E | Missense Mutation (SNP) | VAF 433/992 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VWDE | c.80del p.G27Dfs*27 | Frame Shift Del (DEL) | VAF 97/446 reads (22%) | called by mutect2, pindel, varscan2
- WSCD1 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZC3H12B | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 138/258 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFPM2 | c.2497A>T p.S833C | Missense Mutation (SNP) | VAF 132/489 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZFYVE16 | c.3823G>C p.E1275Q | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ZIK1 | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 73/522 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- ZNF208 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 140/325 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNF280A | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 236/1576 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZNF559 | c.879A>T p.R293S | Missense Mutation (SNP) | VAF 188/485 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF569 | c.1671A>T p.K557N | Missense Mutation (SNP) | VAF 270/721 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF681 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 144/407 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZNF716 | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ABCC12 | c.3522C>T p.A1174= | Silent (SNP) | VAF 121/660 reads (18%) | called by muse, varscan2
- ADAMTS19 | c.1881G>A p.K627= | Silent (SNP) | VAF 84/300 reads (28%) | catalogued as rs766354573; called by muse, varscan2
- ADGRG2 | c.1080C>T p.S360= (on ENST00000379869 / NM_001079858.3; = p.S357= on NM_005756.4) | Silent (SNP) | VAF 165/315 reads (52%) | catalogued as rs774854344; called by muse, mutect2, varscan2
- AP4B1 | c.654A>T p.V218= | Silent (SNP) | VAF 132/530 reads (25%) | called by muse, mutect2
- CACNG3 | c.24C>T p.I8= | Silent (SNP) | VAF 87/355 reads (25%) | catalogued as rs777123441, COSV99135441, COSV99135533; called by muse, mutect2, varscan2
- CCDC151 | c.987A>G p.L329= | Silent (SNP) | VAF 265/607 reads (44%) | catalogued as rs1388624564, COSV62697445; called by muse, mutect2, varscan2
- CD36 | c.993C>T p.S331= | Silent (SNP) | VAF 53/217 reads (24%) | catalogued as rs745750711; called by muse, varscan2
- CFAP46 | c.6876A>C p.T2292= | Silent (SNP) | VAF 88/316 reads (28%) | called by mutect2, varscan2
- CSNKA2IP | c.1734G>A p.A578= | Silent (SNP) | VAF 106/320 reads (33%) | catalogued as rs770127687; called by muse, varscan2
- DAZAP1 | c.1131C>T p.S377= | Silent (SNP) | VAF 200/1008 reads (20%) | catalogued as rs766812291, COSV51831543; called by muse, mutect2, varscan2
- DHX38 | c.1326C>T p.I442= | Silent (SNP) | VAF 22/455 reads (5%) | called by muse, mutect2
- DNAAF4 | c.591T>C p.Y197= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs140091387; called by muse, mutect2, varscan2
- DNAH2 | c.996A>G p.A332= | Silent (SNP) | VAF 96/409 reads (23%) | called by muse, mutect2, varscan2
- DNAH5 | c.11793T>A p.P3931= | Silent (SNP) | VAF 72/426 reads (17%) | called by muse, mutect2, varscan2
- DPP6 | c.996C>T p.T332= (on ENST00000377770 / NM_001364500.2; = p.T270= on NM_001936.5) | Silent (SNP) | VAF 106/314 reads (34%) | catalogued as rs371237236; called by muse, varscan2
- DYNC2H1 | c.5985G>A p.A1995= | Silent (SNP) | VAF 105/347 reads (30%) | catalogued as rs771297555, COSV62094709; called by muse, varscan2
- FAT3 | c.2637C>T p.I879= | Silent (SNP) | VAF 144/344 reads (42%) | catalogued as rs1565252211; called by muse, mutect2, varscan2
- FRS2 | c.543A>G p.E181= | Silent (SNP) | VAF 85/350 reads (24%) | called by muse, mutect2, varscan2
- GDF11 | c.553C>A p.R185= | Silent (SNP) | VAF 168/739 reads (23%) | catalogued as COSV99069998; called by muse, mutect2, varscan2
- GJB4 | c.75G>T p.L25= | Silent (SNP) | VAF 192/653 reads (29%) | called by muse, mutect2, varscan2
- GOSR1 | c.309C>T p.A103= | Silent (SNP) | VAF 95/431 reads (22%) | called by muse, mutect2, varscan2
- HTR1A | c.1137C>A p.T379= | Silent (SNP) | VAF 148/427 reads (35%) | called by muse, varscan2
- HTR1B | c.18T>A p.A6= | Silent (SNP) | VAF 111/547 reads (20%) | called by muse, mutect2, varscan2
- INPPL1 | c.1962G>A p.E654= | Silent (SNP) | VAF 94/1814 reads (5%) | called by muse, mutect2
- IQSEC3 | c.234C>A p.A78= | Silent (SNP) | VAF 986/2080 reads (47%) | called by muse, varscan2
- KCNAB1 | c.411T>C p.D137= (on ENST00000490337 / NM_172160.3; = p.D126= on NM_003471.3) | Silent (SNP) | VAF 202/462 reads (44%) | called by muse, mutect2, varscan2
- KLK1 | c.600C>T p.V200= | Silent (SNP) | VAF 93/561 reads (17%) | catalogued as rs754921741; called by muse, mutect2, varscan2
- LRRC15 | c.153G>A p.L51= | Silent (SNP) | VAF 199/1153 reads (17%) | catalogued as COSV61649841; called by muse, mutect2, varscan2
- LTC4S | c.372C>A p.L124= | Silent (SNP) | VAF 284/954 reads (30%) | called by muse, mutect2, varscan2
- MOCS3 | c.1155C>T p.S385= | Silent (SNP) | VAF 102/384 reads (27%) | catalogued as rs1312122100; called by muse, varscan2
- MTX2 | c.9A>T p.L3= | Silent (SNP) | VAF 199/1049 reads (19%) | called by muse, mutect2, varscan2
- MYH2 | c.3105A>G p.Q1035= | Silent (SNP) | VAF 124/472 reads (26%) | called by muse, mutect2, varscan2
- NF1 | c.4671A>T p.T1557= (on ENST00000358273 / NM_001042492.3; = p.T1536= on NM_000267.3) | Silent (SNP) | VAF 140/499 reads (28%) | called by muse, mutect2, varscan2
- NLRP9 | c.1521G>T p.L507= | Silent (SNP) | VAF 149/764 reads (20%) | called by muse, varscan2
- NOS2 | c.2094C>T p.Y698= | Silent (SNP) | VAF 118/541 reads (22%) | called by muse, mutect2, varscan2
- OR11H12 | c.906C>T p.P302= | Silent (SNP) | VAF 118/590 reads (20%) | catalogued as rs1483811827; called by muse, varscan2
- OR4F4 | c.564A>G p.L188= | Silent (SNP) | VAF 91/756 reads (12%) | called by muse, varscan2
- OR52K2 | c.429C>T p.I143= | Silent (SNP) | VAF 137/571 reads (24%) | called by muse, mutect2, varscan2
- OR8H3 | c.171C>T p.H57= | Silent (SNP) | VAF 120/560 reads (21%) | called by muse, varscan2
- PACSIN3 | c.261G>A p.A87= | Silent (SNP) | VAF 216/880 reads (25%) | catalogued as rs960798354, COSV54067455; called by muse, mutect2, varscan2
- PCDH15 | c.1731G>T p.R577= | Silent (SNP) | VAF 114/434 reads (26%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1713T>A p.G571= | Silent (SNP) | VAF 238/899 reads (26%) | called by muse, varscan2
- PCDHB14 | c.1185G>T p.P395= | Silent (SNP) | VAF 118/446 reads (26%) | catalogued as rs781836475, COSV53389869; called by muse, varscan2
- PNLIPRP1 | c.432C>A p.G144= | Silent (SNP) | VAF 131/507 reads (26%) | catalogued as COSV62612896; called by muse, varscan2
- PNPLA5 | c.66C>A p.A22= | Silent (SNP) | VAF 261/883 reads (30%) | catalogued as rs1317093021; called by muse, mutect2, varscan2
- POM121L2 | c.1029A>T p.A343= | Silent (SNP) | VAF 125/436 reads (29%) | called by muse, varscan2
- PRLR | c.807G>T p.P269= | Silent (SNP) | VAF 62/420 reads (15%) | catalogued as rs200768734, COSV51494007; called by muse, mutect2, varscan2
- RASIP1 | c.2664C>G p.P888= | Silent (SNP) | VAF 368/811 reads (45%) | called by muse, mutect2, varscan2
- REPS2 | c.459A>G p.P153= | Silent (SNP) | VAF 134/286 reads (47%) | called by muse, mutect2, varscan2
- RGS3 | c.3312G>A p.L1104= (on ENST00000350696 / NM_001282923.2; = p.L823= on NM_130795.4) | Silent (SNP) | VAF 134/604 reads (22%) | called by muse, mutect2, varscan2
- RRAS | c.252C>T p.T84= | Silent (SNP) | VAF 122/567 reads (22%) | catalogued as rs202189880, COSV55869057; called by muse, mutect2, varscan2
- SALL1 | c.2436C>A p.S812= | Silent (SNP) | VAF 296/686 reads (43%) | catalogued as rs749605203; called by muse, varscan2
- SCAI | c.255G>A p.K85= (on ENST00000336505 / NM_001144877.3; = p.K108= on NM_173690.5) | Silent (SNP) | VAF 105/385 reads (27%) | called by muse, mutect2, varscan2
- SMG7 | c.1995G>A p.P665= | Silent (SNP) | VAF 319/509 reads (63%) | catalogued as rs561881733; called by muse, mutect2, varscan2
- SNX12 | c.210G>A p.R70= | Silent (SNP) | VAF 112/224 reads (50%) | called by muse, mutect2, varscan2
- SOX11 | c.954C>A p.I318= | Silent (SNP) | VAF 188/751 reads (25%) | called by muse, varscan2
- ST6GALNAC3 | c.723C>A p.T241= | Silent (SNP) | VAF 88/351 reads (25%) | catalogued as rs767948772, COSV60322540; called by muse, mutect2, varscan2
- TENT4A | c.642G>C p.G214= | Silent (SNP) | VAF 239/1187 reads (20%) | called by muse, mutect2, varscan2
- THEMIS | c.606T>A p.L202= | Silent (SNP) | VAF 117/473 reads (25%) | called by muse, mutect2, varscan2
- TP53BP2 | c.2571A>G p.P857= (on ENST00000343537 / NM_001031685.3; = p.P728= on NM_005426.2) | Silent (SNP) | VAF 393/630 reads (62%) | called by muse, mutect2, varscan2
- TRIM74 | c.624G>T p.L208= | Silent (SNP) | VAF 154/731 reads (21%) | called by muse, varscan2
- TSPYL5 | c.471G>T p.G157= | Silent (SNP) | VAF 256/906 reads (28%) | called by muse, mutect2, varscan2
- VCAN | c.2895T>G p.T965= | Silent (SNP) | VAF 88/262 reads (34%) | catalogued as rs141161041; called by muse, varscan2
- ZFP69B | c.1455G>A p.R485= | Silent (SNP) | VAF 144/576 reads (25%) | called by muse, varscan2
- BRD2 | c.-945G>T | 5'UTR (SNP) | VAF 99/348 reads (28%) | called by muse, varscan2
- CPLANE1 | c.*2266C>G | 3'UTR (SNP) | VAF 65/450 reads (14%) | catalogued as COSV57056422; called by muse, mutect2, varscan2
- CRYBG2 | chr1:26354319 G>A | 5'Flank (SNP) | VAF 54/928 reads (6%) | called by muse, mutect2
- DDX41 | c.*267C>T | 3'UTR (SNP) | VAF 132/500 reads (26%) | called by muse, varscan2
- EHMT1 | c.2382+1711C>G | Intron (SNP) | VAF 99/390 reads (25%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23823G>T | Intron (SNP) | VAF 134/506 reads (26%) | called by muse, varscan2
- KIAA1958 | c.1172-27416A>G | Intron (SNP) | VAF 125/492 reads (25%) | called by muse, varscan2
- MASP1 | c.1303+5314C>A | Intron (SNP) | VAF 198/1088 reads (18%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1900C>A | Intron (SNP) | VAF 144/361 reads (40%) | catalogued as rs771435947; called by muse, mutect2, varscan2
- NPR3 | chr5:32710717 G>A | 5'Flank (SNP) | VAF 84/538 reads (16%) | called by muse, mutect2, varscan2
- NRSN1 | c.190-4382A>T | Intron (SNP) | VAF 58/253 reads (23%) | called by muse, mutect2, varscan2
- OR1N2 | c.-30T>A | 5'UTR (SNP) | VAF 94/404 reads (23%) | catalogued as COSV65460290; called by muse, mutect2
- RIMBP2 | c.102+8190G>T | Intron (SNP) | VAF 126/498 reads (25%) | called by muse, mutect2, varscan2
- RTL10 | c.*258G>T | 3'UTR (SNP) | VAF 202/518 reads (39%) | called by muse, mutect2, varscan2
- SHOC2 | c.-164G>T | 5'UTR (SNP) | VAF 82/358 reads (23%) | called by muse, mutect2, varscan2
- SLC17A2 | c.*74dup | 3'UTR (INS) | VAF 146/621 reads (24%) | called by mutect2, pindel, varscan2
- SLITRK2 | chrX:145827784 C>A | 3'Flank (SNP) | VAF 76/194 reads (39%) | catalogued as COSV59428513; called by muse, mutect2, varscan2
- TTN | c.33340+409C>A | Intron (SNP) | VAF 126/341 reads (37%) | called by muse, varscan2
- Z99774.2 | chr22:26671871 A>G | 5'Flank (SNP) | VAF 120/781 reads (15%) | called by muse, mutect2, varscan2
